Surgical pathology report (de-identified scan), TCGA case TCGA-56-7823, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-7823-01B (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

*** CORRECTED REPORT ***

CORRECTED REPORT: FINAL DIAGNOSIS PART D

This report is issued to reflect a change in the final diagnosis section part D to correct the total number of lymph nodes to 18 which includes the two positive lymph nodes in the lobectomy specimen.
The correction does not modify the previous diagnostic information.

DIAGNOSIS

DIAGNOSIS:

A. Level 10 lymph nodes:

Metastatic squamous cell carcinoma in one of five lymph nodes (1/5).

B. Level 4 lymph nodes:

Five benign hyperplastic regional lymph nodes (0/5).

C. Level 11 lymph nodes:

Metastatic squamous cell carcinoma in one of five lymph nodes (1/5).

D. Right upper lung lobectomy:

Carcinoma.

Tumor Characteristics:

1. Histologic type: Squamous cell carcinoma.
2. Histologic grade: Moderately to poorly differentiated (G2-3).
3. Tumor site: Two masses are present, one of which is central and the other which is peripheral.
4. Tumor focality: Multifocal, see comment.
5. Tumor size: Largest mass 2.8 x 2.5 x 2.0 cm, smaller mass 2.6 x 2.5 x 2.0 cm.
6. Visceral pleural invasion: Not identified.
7. Lymphovascular space invasion: Present.
8. Tumor extension: Tumor confined to lung.
9. Treatment effect: Not identified.

Surgical Margin Status:

1. Tumor distance from bronchial margin: 0.5 cm.
2. Tumor distance from parenchymal (stapled) margin: 3.5 cm.
3. Tumor distance from pleural surface: Approximately 0.1 cm.

Lymph Node Status:

1. Total number of lymph nodes received (utilizing all specimens submitted): 18.
2. Total number of lymph nodes containing metastatic carcinoma: 4 (4/18).

Other:

1. Other significant findings: None.
2. pTNM stage: pT1b, N1.

E. Level 7 lymph node:

Solitary benign hyperplastic lymph node (0/1).

COMMENTS:

The two masses in the lung appear microscopically essentially identical and given the presence of lymphovascular space invasion it is favored that rather than these being metachronous carcinomas instead one represents lymphovascular space or intraparenchymal metastasis.

[page 2 of 2]
CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: female with right upper lobe squamous cell cancer.

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Level 10 lymph node
- B. Level 4 lymph node
- C. Level 11 lymph node
- D. Right upper lobe
- E. Level 7 lymph node

SPECIMEN DATA

GROSS DESCRIPTION:

A. First container A is labeled with the patient name Level 10 lymph node. The specimen consists of five gray-tan to brown-tan nodules consistent with lymph nodes that measure from 0.7 to 1.5 cm. The lymph nodes are entirely submitted in cassettes labeled as follows: Two probable nodes each bisected block 1; Two probable nodes block 2; One probable node trisected block 3.

B. Second container B is labeled with the patient's name, Level 4 lymph node. The specimen consists of a piece of yellow-tan fibroadipose tissue 3.5 x 1.5 x 1 cm. Sectioning reveals five probable lymph nodes that measure from 0.7 to 1 cm in greatest dimension. The lymph nodes are entirely submitted in cassettes labeled as follows: Three probable nodes block 1; One probable node bisected block 2; One probable node bisected block 3.

C. Third container C is labeled with the patient's name, Level 11 lymph node. The specimen consists of five gray-brown nodules consistent with lymph nodes that measure from 0.7 to 1.2 cm. The lymph nodes are entirely submitted in cassettes labeled as follows: Three probable nodes block 1; Two probable nodes each bisected block 2.

D. The fourth container D is labeled with the patient name, Right upper lobe. The specimen consists of a lung lobectomy specimen that measures 16 x 10 x 2.5 cm and weighs 203 grams. The pleural surface is gray-tan to purple-gray slightly anthracotic. The pleural surface has been inked. Sectioning reveals a yellow-gray slightly anthracotic mass that measures 2.8 x 2.5 x 2 cm that is within 0.1 cm of the pleural margin, comes within 0.5 cm of the bronchial margin. The mass appears to be within the bronchus. The mass is within 3.5 cm of the stapled edge. There is a second lesion identified that measures 2.6 x 2.5 x 2 cm that is within 0.1 cm of the pleural surface displays areas of puckering of the overlying pleura. There is also a central cavity within this lesion measuring 1.7 cm. This lesion is within 4.2 cm of the bronchial margin. The surrounding lung tissue is brown-tan spongy. No other lesions are identified. Within the surrounding peribronchial soft tissue there are two gray-brown nodules consistent with lymph nodes measuring 1 and 1.5 cm. Received with the specimen are two cassettes one green, one yellow labeled with the yellow one additionally labeled and the green one additionally labeled. Representative sections are submitted in cassettes labeled as follows: Sections from the first lesion in blocks 1-4; Bronchial vascular margin block 5; Shave sectioned from stapled edge block 6; Sections from the second lesion in blocks 7-10; Surrounding uninvolved lung block 11; Each of the peribronchial lymph nodes bisected as follows: One probable node block 12; One probable node block 13.

E. The container E is labeled with the patient's name Level 7 lymph node. The specimen consists of a gray-tan nodule consistent with lymph node measuring 1.5 x 0.5 x 0.5 cm. The lymph node is bisected and entirely submitted in a single cassette labeled

Source: NCI Genomic Data Commons file 2db0bcb2-2e91-4f35-9b28-61e122f3667e (TCGA-56-7823.6B37394D-C1FA-4E01-86C7-4AA00588EBA9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).